BEATAML1.0 case 2635 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/57fcfedd-ff63-4390-840b-135535f9e794

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia with t(8;21)(q22;q22), RUNX1-RUNX1T1: ICD-O-3 morphology code: 9896/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 41.8 years (15,278 days); Progression or recurrence: no.

Biospecimens (1 sample)
- Sample BA3387D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
